Somatic mutation profile of tumor specimen TCGA-57-1992-01A (aliquot TCGA-57-1992-01A-01W-0699-08) from TCGA case TCGA-57-1992, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3.
Specimen TCGA-57-1992-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 959d8232-3e2a-4167-ac9a-1e734efcc777.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-57-1992-11A (Solid Tissue Normal), aliquot TCGA-57-1992-11A-01W-0700-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bba2e97-8e4c-4f9c-91d5-ff791953bf4c

The open-access MAF lists 75 somatic variants for this specimen: 52 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Frame Shift Del 4, RNA 2, Splice Site 2, Frame Shift Ins 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 40/157 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO5 | c.994A>G p.M332V | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs200553437, COSV100201350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO8 | c.3310dup p.R1104Pfs*114 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | catalogued as rs767832066; called by pindel, varscan2
- BRINP3 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs553670519, COSV66533368; called by muse, mutect2, varscan2
- CDH23 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.473); catalogued as rs552718415, COSV99818688; called by muse, mutect2
- CFAP206 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452052996, COSV99739069; called by muse, mutect2, varscan2
- CFAP54 | c.4775C>G p.S1592C | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.789); catalogued as COSV100732920; called by muse, mutect2, varscan2
- DNAH8 | c.4037G>A p.C1346Y | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100543164; called by muse, mutect2
- EPHX1 | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99688695; called by muse, mutect2
- EPN2 | c.1493C>A p.A498D | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV100127326; called by muse, mutect2, varscan2
- FBXW9 | c.1172T>A p.F391Y (on ENST00000587955; = p.F371Y on NM_032301.3) | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV100981952; called by muse, mutect2
- FER1L6 | c.5108C>G p.S1703C | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205412; called by muse, mutect2
- FIGNL1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100794831; called by muse, mutect2
- HORMAD1 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100463806, COSV59271078; called by muse, mutect2, varscan2
- IRF6 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 217/369 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as CD133987, CX092427, COSV99670925; called by muse, mutect2, varscan2
- JOSD1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV99322602; called by muse, mutect2, varscan2
- KBTBD4 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV99772206; called by muse, varscan2
- MACF1 | c.15190C>A p.L5064M (on ENST00000372915; = p.L2997M on NM_012090.5) | Missense Mutation (SNP) | VAF 37/327 reads (11%) | catalogued as COSV99241024; called by muse, mutect2, varscan2
- MKI67 | c.6963G>T p.E2321D | Missense Mutation (SNP) | VAF 87/819 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100896143; called by muse, mutect2, varscan2
- MOV10 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100659382; called by muse, mutect2, varscan2
- NAV1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as COSV99818135; called by muse, mutect2, varscan2
- NEB | c.18286G>A p.E6096K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.992); catalogued as COSV99414455; called by mutect2, varscan2
- NHLRC2 | c.1580C>A p.T527K | Missense Mutation (SNP) | VAF 27/648 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.081); catalogued as COSV100992888; called by muse, mutect2
- NOX1 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.597); catalogued as rs138268462, COSV99471410; called by muse, mutect2, varscan2
- PGBD5 | c.383G>T p.R128L (on ENST00000525115; = p.R197L on NM_001258311.2) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV100358354, COSV58411486; called by muse, mutect2, varscan2
- PHKA1 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs782566958, COSV100262433; called by muse, varscan2
- PPOX | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99237112; called by muse, mutect2
- PPP6R2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771909622, COSV99323811; called by muse, mutect2, varscan2
- PSIP1 | c.1210del p.R404Gfs*8 | Frame Shift Del (DEL) | VAF 33/66 reads (50%) | catalogued as COSV66253598, COSV66255063; called by mutect2, pindel, varscan2
- RC3H2 | c.2539T>C p.C847R | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as COSV100605298; called by muse, mutect2, varscan2
- RESF1 | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100440072; called by muse, mutect2
- RGS3 | c.577G>A p.V193I (on ENST00000350696 / NM_001282923.2; = p.V81I on NM_017790.4) | Missense Mutation (SNP) | VAF 136/378 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs770598136, COSV58285615, COSV99048032; called by muse, mutect2, varscan2
- RSKR | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 38/1190 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99971909; called by muse, mutect2
- SELENOP | c.764A>T p.Q255L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV100736705; called by muse, mutect2, varscan2
- SLC47A2 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.401); catalogued as COSV100327827; called by mutect2, varscan2
- SLC6A2 | c.1148-1G>A p.X383_splice | Splice Site (SNP) | VAF 40/262 reads (15%) | catalogued as COSV99573280; called by muse, mutect2, varscan2
- SUN2 | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV99322896; called by muse, mutect2, varscan2
- TMX4 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99851334; called by muse, mutect2
- UQCC1 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100568266; called by muse, mutect2
- USP43 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 87/134 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99556326; called by muse, mutect2, varscan2
- ZMYND8 | c.1268G>A p.R423Q (on ENST00000311275 / NM_001363741.2; = p.R443Q on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs568551781, COSV99519466; called by muse, mutect2, varscan2
- ZNF234 | c.1672C>A p.H558N | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101468332; called by muse, mutect2
- ABCB6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2
- ARID1A | c.2591_2592delinsT p.G864Vfs*27 | Frame Shift Del (DEL) | VAF 60/160 reads (38%) | called by pindel, varscan2*
- CIR1 | c.1215del p.K405Nfs*42 | Frame Shift Del (DEL) | VAF 66/498 reads (13%) | called by mutect2, pindel, varscan2
- DLG5 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- KAZN | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- L3MBTL4 | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 92/352 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by mutect2, varscan2
- MYBL1 | c.688-6_710del p.X230_splice | Splice Site (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- NRXN2 | c.1904dup p.R636Pfs*32 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by pindel, varscan2
- POLH | c.1225_1227del p.S409del | In Frame Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- WNK1 | c.1083del p.G362Afs*13 | Frame Shift Del (DEL) | VAF 87/487 reads (18%) | called by mutect2, pindel, varscan2
- ADGRL1 | c.15C>T p.A5= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs532448974, COSV100529241; called by muse, varscan2
- CAB39L | c.1013G>A p.*338= | Silent (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- CHD6 | c.8097G>T p.G2699= | Silent (SNP) | VAF 18/632 reads (3%) | catalogued as COSV100950528; called by muse, mutect2
- ILDR1 | c.1179G>A p.R393= (on ENST00000344209 / NM_001199799.2; = p.R349= on NM_175924.4) | Silent (SNP) | VAF 64/264 reads (24%) | catalogued as COSV56550059, COSV56551517; called by muse, mutect2, varscan2
- MAP3K13 | c.2715G>T p.G905= | Silent (SNP) | VAF 19/378 reads (5%) | catalogued as COSV99406356; called by muse, mutect2
- MOV10 | c.1464G>C p.V488= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV100659384; called by muse, mutect2, varscan2
- NLRP7 | c.1575C>T p.L525= | Silent (SNP) | VAF 48/765 reads (6%) | catalogued as rs1327980893, COSV60182405; called by muse, mutect2
- OR1A1 | c.486C>T p.L162= | Silent (SNP) | VAF 77/471 reads (16%) | catalogued as COSV100410711; called by muse, mutect2, varscan2
- PCDHGA8 | c.720G>T p.P240= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as rs1475648389, COSV53895150, COSV99530055; called by muse, mutect2, varscan2
- PLK2 | c.1428A>G p.A476= | Silent (SNP) | VAF 98/136 reads (72%) | catalogued as COSV99955781; called by muse, mutect2, varscan2
- PLSCR5 | c.744C>A p.V248= | Silent (SNP) | VAF 14/380 reads (4%) | catalogued as COSV101494465; called by muse, mutect2
- PRICKLE3 | c.1398C>T p.F466= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs1339654414, COSV100889885; called by muse, mutect2, varscan2
- RNF213 | c.6144G>A p.Q2048= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100299630; called by muse, mutect2
- SLC25A15 | c.831C>T p.F277= | Silent (SNP) | VAF 110/274 reads (40%) | catalogued as COSV100090700; called by muse, mutect2, varscan2
- SLC28A2 | c.1167C>T p.F389= | Silent (SNP) | VAF 21/326 reads (6%) | catalogued as COSV100754605; called by muse, mutect2
- THOC5 | c.864G>A p.V288= | Silent (SNP) | VAF 351/1021 reads (34%) | catalogued as COSV100803443; called by muse, mutect2, varscan2
- TMPRSS4 | c.204C>T p.L68= | Silent (SNP) | VAF 52/939 reads (6%) | catalogued as COSV101449347, COSV71109080; called by muse, mutect2
- TOP1 | c.2016C>A p.A672= | Silent (SNP) | VAF 20/658 reads (3%) | catalogued as COSV100793660; called by muse, mutect2
- TREML1 | c.30C>T p.L10= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV100632482; called by muse, mutect2
- UNC13A | c.2293C>T p.L765= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV99407028; called by muse, mutect2, varscan2
- USP28 | c.2502A>G p.Q834= | Silent (SNP) | VAF 127/184 reads (69%) | catalogued as rs1236176363, COSV99134455; called by muse, mutect2, varscan2
- DCHS2 | n.1667C>A | RNA (SNP) | VAF 8/88 reads (9%) | catalogued as rs1274554248, COSV100250805; called by muse, mutect2
- STAG3L4 | n.545C>G | RNA (SNP) | VAF 183/337 reads (54%) | catalogued as rs1238360942; called by muse, varscan2
